MMRF case MMRF_1676 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/44a131d8-88d4-4068-bc2f-6db35d7bddc0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.1 years (18,666 days); ISS stage: I; Days to last known disease status: 1,174 days (3.2 years); Days to last follow up: 1,174 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 178 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 179 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 181 days; Days to treatment end: 181 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 271 days; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 327 days; Days to treatment end: 354 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 355 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 4.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 56.5 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.29 mmol/L; Albumin 37 g/L; Total Protein 11.2 g/dL; Glucose 4.4 mmol/L.
- Day 84 (ECOG 1): M Protein 8.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 73 µmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.6 mmol/L.
- Day 173 (ECOG 1): M Protein 8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.4 mmol/L.
- Day 264 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.31 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 355 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 9.7 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.37 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.1 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.5 mmol/L.
- Day 530 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.37 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.3 mmol/L.
- Day 614 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 2.94 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.36 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.5 mmol/L.
- Day 727 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 2.96 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 4.9 mmol/L.
- Day 810 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.32 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.3 mmol/L.
- Day 894 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 2.8 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.37 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.8 mmol/L.
- Day 978 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 7.1 g/L; Immunoglobulin A 2.99 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.34 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.4 mmol/L.
- Day 1,092 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 7.9 g/L; Immunoglobulin A 3.43 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 80 µmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5 mmol/L.
- Day 1,174 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 76 µmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 3.3 mmol/L.

Other clinical attributes
- Day -2: Weight: 72 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1676_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1676_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
